Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OW, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OW-01A (Primary Tumor).

[page 1 of 2]
PAGE #: 1
SEX: F

PROCEDURE: SPHS

Year-old female with prior gastric stapling procedure for obesity and has now developed a distal esophageal Barrett's carcinoma. Operative procedure: Transhiatal esophagectomy. Peripancreatic soft tissue frozen.

ICD-O-3

Adenocarcinoma, NOS 8140/3

Site: esophagus, distal third
CIS-5

PROCEDURE: SPGD

1. "Peripancreatic soft tissue FS" Received fresh in a small container is a 2.0 x 1.1 x 0.3 cm soft tissue.

1A.&B. Frozen section control.

2. "Low paraesophageal left lymph node FS" Received fresh in a small container is a lymph node, 1.1 cm, bisected.
Frozen section control.

3. "Thoracic esophagus" Received in a small container is a 7.2 cm segment of distal esophagus with an attached 7.0 x 4.0 x 3.5 cm stomach. Attached to the distal portion of the stomach is a 4.8 cm segment of bowel, stapled at the margin. The GE junction is remarkable for a 3.1 x 2.3 cm fungating lesion extending 1.6 cm to involve the esophagus, and 2.8 cm to involve the stomach, it is tan-red and centrally ulcerated. The mass extending to within 6.0 cm of the esophageal margin, and 7.8 cm of the bowel margin. The surface corresponding this area is inked black. Sectioning of the mass reveals ill-defined tan-white cut surfaces grossly abutting the muscularis, with a maximum thickness of 1.9 cm. The remaining esophageal mucosa is pink-tan grossly unremarkable with an internal circumference of 4.5 cm and a wall thickness of 1.0 cm. The gastric mucosa is tan, with grossly unremarkable rugal folds. At the junction of the anastomosis between the bowel and the stomach is a 0.8 x 0.5 cm full-thickness defect. The bowel mucosa is red-brown, hemorrhagic. Attached adipose tissue has ten possible lymph nodes ranging from 0.2 to 0.8 cm. 3A. Tumor to esophageal mucosa.

3B. Tumor to gastric mucosa.

3C.-E. Remaining tumor.

3F. Anastomosis.

3G. Aforementioned full-thickness defect to bowel margin.

3H. Five whole possible lymph nodes.

3I. Four whole possible lymph nodes.

3J. Largest possible lymph node. Bisected.

4. "Cervical margin" Received in a small container is a 1.7 cm segment of esophagus with a grossly unremarkable trans surface. It is lined by tan-white grossly unremarkable mucosa. Wall thicknesses averages to 0.8 cm. The end opposite the stapled end is shaved and submitted in one cassette.

FROZEN SECTION REPORT:

1A.&B. One lymph node negative for carcinoma.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F

2. Metastatic adenocarcinoma.

have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section reports.

PROCEDURE: SPN1

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma, spanning the GE junction.

Depth of invasion: Muscularis propria.

Number of positive lymph nodes: 2/11.

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative and expansile.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T2 N1 Mx.

PROCEDURE: SPDX

1. Lymph node, peripancreatic, excision: One lymph node negative for carcinoma.

2. Lymph node, left low paraesophageal, excision: Metastatic adenocarcinoma in one lymph node.

3&4. Esophagus, resection: Invasive adenocarcinoma spanning the GE junction, extending into the muscularis propria. Metastatic carcinoma in two of eleven lymph nodes. Margins negative. Please see template for details.

the signing staff pathologist, have personally examined

Dual/Synchronous Primary (Noted)		

10/9/12

Source: NCI Genomic Data Commons file 1b4618b9-5b44-43b3-b2dd-27a3ec908c7d (TCGA-L5-A4OW.104F14E5-32DF-4DEF-BB06-307DC8FEE6A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).